FM case AD4034 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Small intestine.
https://portal.gdc.cancer.gov/cases/02beba38-7da3-48a8-97b4-c0db544681bc

Male, 64.4 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the duodenum; metastasis biopsied or resected from the abdomen. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
